Surgical pathology report (de-identified scan), TCGA case TCGA-AF-2692, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-AF-2692-01A (Primary Tumor).

[page 1 of 2]
TCGA-AF-2692

SPECIMEN

- A. Right uterine adnexa
- B. Sigmoid and upper half rectum
- C. Appendix

CLINICAL NOTES

PRE-OP DIAGNOSIS: Rectosigmoid cancer

FROZEN SECTION DIAGNOSIS

- A. Ovary, right, resection: Mucinous cystic neoplasm. Negative for malignancy on frozen section.

GROSS DESCRIPTION

A. The specimen is received unfixed labelled "right uterine adnexa" and consists of a pink uterine tube measuring 4 cm in length and 0.7 cm in diameter. There is adjacent tan ovary measuring 2.5 x 1.3 cm with a contained cyst measuring 3.5 cm in diameter. The cyst contains green mucoid material. No papillations or solid areas are seen. A portion of the cyst wall is

taken for frozen section diagnosis as requested. Additional sections after fixation. RS-6.

B. The specimen is received unfixed labeled "sigmoid and upper half of rectum and consists of a segment of large bowel measuring 24 cm. in length and 2.2 cm. in diameter. The peritoneal reflection is present and is 3.7 cm. from the distal stapled margin. The external surface of the rectal portion of the specimen is inked. The rectal resection specimen is complete and has a smooth surface. There is abundant pericolic fat and the entire specimen is up to 8.5 cm. in diameter. The specimen will be opened on the antimesenteric surface to harvest tissue for research.

There is a fungating red tumor on the mucosal surface on the mesenteric side of the specimen measuring 3.5 x 3.7 x 1.7 cm. There is a small white polyp proximal to the tumor measuring 0.4 cm. in diameter to 0.7 cm. from the tumor. The fat from the tissue above

GROSS DESCRIPTION

the peritoneal reflection will be cleared. The tumor itself is just below the peritoneal reflection. On cut section the gross tumor is 2.5 cm from the rectal margin radially.

BLOCK SUMMARY: 1 & 2 - Margins of resection; 3-5 - tumor; 6 & 7 - rectal lymph nodes; 8-17 - pericolic lymph nodes.

C. The specimen is received in formalin labeled "appendix"

and consists of a white appendix measuring 5 x 0.5 x 0.4 cm. with a small amount of adherence mesoappendix measuring 4 x 0.5 x 0.2 cm. RS-2 The tip of the appendix on the proximal end are in block #1.

[page 2 of 2]
MICROSCOPIC DESCRIPTION

- A. Benign mucinous cyst adenoma is present.
- B. Tumor type: Colonic adenocarcinoma. There is some mucinous differentiation (less than 50%).
- Tumor grade: 1-2 out of 3
- Tumor size: 3.7 x 3.5 x 1.7 cm
- Distance to nearest margin: I didn't measure this,

but

examination of the dissected specimen shows the distance to be at least 3.5 cm.

Level of penetration: Carcinoma penetrates through the

muscularis propria into pericolic soft tissue.

- Margins of resection: Negative for malignancy
- Vascular invasion: Absent
- Host response: Mild chronic inflammation
- Attached lymph nodes: There is no evidence of malignancy in any of 12 pericolic lymph nodes.
- Non-lymph node pericolic tumor: Absent
- pTNM Stage: T3 N0

MICROSCOPIC DESCRIPTION

Other findings: None

DIAGNOSIS

- A. Ovary, right, resection: Benign mucinous cystadenoma.
- B. Sigmoid, upper half of rectum, segmental resection:
- Colonic adenocarcinoma of the rectum.

Note: Carcinoma invades through the muscularis propria into perirectal soft tissue. The margins of resection are negative for malignancy. There is no evidence of malignancy in any of 12 pericolic lymph nodes.

- C. Appendix, resection: Fibrous obliteration of the distal appendiceal lumen.
-

Source: NCI Genomic Data Commons file 0827f687-7ef7-447f-8ac3-a7c884346238 (TCGA-AF-2692.F7C16E9D-EE46-465A-8D53-0CC9B999C0EC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).